Somatic mutation profile of tumor specimen TCGA-D3-A51G-06A (aliquot TCGA-D3-A51G-06A-11D-A25O-08) from TCGA case TCGA-D3-A51G, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D3-A51G-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 302eb82a-041c-478d-a7fd-2531c5eb2dc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51G-10A (Blood Derived Normal), aliquot TCGA-D3-A51G-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcf1eb35-0aa4-4bf1-97ab-3c4e01e4d31d

The open-access MAF lists 1,473 somatic variants for this specimen: 935 protein-altering or splice-affecting, 505 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 851, Silent 505, Nonsense Mutation 46, Splice Site 16, Intron 13, Splice Region 11, RNA 11, 3'UTR 4, Translation Start Site 3, Frame Shift Del 3, 3'Flank 2, In Frame Del 2.

Variants (750 of 1,473; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.973); catalogued as rs267606631, CM094418, COSV59510069; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- EBF2 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 42/100 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV68776268, COSV68778111; called by muse, mutect2, varscan2
- MTM1 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 25/29 reads (86%) | catalogued as rs587783805, CM001733, COSV60335653; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 157/191 reads (82%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 30/37 reads (81%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.4846C>T p.R1616* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs752429062, COSV62137304; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV50962227; called by muse, mutect2, varscan2
- AADACL4 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs986248510, COSV66106561; called by muse, mutect2, varscan2
- ABCA1 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66067500; called by muse, mutect2, varscan2
- ABCA1 | c.469T>C p.F157L | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV66058848; called by muse, mutect2, varscan2
- ABCA12 | c.3455C>T p.S1152L (on ENST00000272895 / NM_173076.3; = p.S834L on NM_015657.3) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753433213, COSV55948030; called by muse, mutect2, varscan2
- ABCA13 | c.3230T>A p.I1077N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV70032510; called by muse, mutect2, varscan2
- ABCA5 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV67017370; called by muse, mutect2, varscan2
- ABCA7 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); catalogued as rs1358480868, COSV54031801; called by muse, mutect2, varscan2
- ABCA7 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54027920; called by muse, mutect2, varscan2
- ABCB5 | c.2067G>A p.W689* (on ENST00000404938 / NM_001163941.2; = p.W244* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | catalogued as COSV51712352; called by muse, mutect2, varscan2
- ABCC3 | c.3185C>T p.T1062I | Missense Mutation (SNP) | VAF 90/117 reads (77%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs374171279, COSV53324009; called by muse, mutect2, varscan2
- ABCC5 | c.3547C>T p.P1183S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.119); catalogued as COSV55592053; called by muse, mutect2, varscan2
- ABCC6 | c.3964G>A p.G1322R | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV52744951; called by muse, mutect2, varscan2
- ABCC9 | c.3182G>A p.G1061D | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53975641; called by muse, mutect2, varscan2
- ABHD3 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56677028; called by muse, mutect2, varscan2
- ABI3BP | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1294019384, COSV52532282; called by muse, mutect2, varscan2
- ABLIM2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV56401289; called by muse, mutect2
- AC100868.1 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV51844815, COSV99226469; called by muse, mutect2, varscan2
- ACAA1 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs369897061; called by muse, mutect2, varscan2
- ACACB | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV58129614; called by muse, mutect2, varscan2
- ACMSD | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV51606597, COSV51607729; called by muse, mutect2, varscan2
- ACOT7 | c.545C>T p.S182F (on ENST00000377855 / NM_181864.3; = p.S172F on NM_007274.4) | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV64113942; called by muse, mutect2, varscan2
- ACOX3 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 33/58 reads (57%) | catalogued as COSV62712470; called by muse, mutect2, varscan2
- ACSF3 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58079119; called by muse, mutect2, varscan2
- ACSM5 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); catalogued as rs759635145, COSV100089725, COSV59372551; called by muse, mutect2, varscan2
- ACTL8 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1168544751, COSV64861750; called by muse, mutect2, varscan2
- ACTL9 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV61006246; called by muse, mutect2, varscan2
- ADAM28 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV56101777, COSV56101830; called by muse, mutect2, varscan2
- ADAM32 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV65950439; called by muse, mutect2, varscan2
- ADAM33 | c.2405C>A p.A802E | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as rs1187394116, COSV62935316; called by muse, mutect2, varscan2
- ADAMDEC1 | c.441-1G>A p.X147_splice | Splice Site (SNP) | VAF 24/61 reads (39%) | catalogued as COSV56475768; called by muse, mutect2, varscan2
- ADAMTS20 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752301075, COSV67126374, COSV67136307; called by muse, mutect2, varscan2
- ADAMTS7 | c.5027C>T p.P1676L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV66307853; called by muse, mutect2, varscan2
- ADCK1 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs776632140, COSV53082116; called by muse, mutect2, varscan2
- ADCY10 | c.4090G>T p.E1364* | Nonsense Mutation (SNP) | VAF 65/95 reads (68%) | catalogued as COSV63241690; called by muse, mutect2, varscan2
- ADGRE1 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV51677032, COSV99165594; called by muse, mutect2, varscan2
- ADGRG4 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54959077; called by muse, mutect2, varscan2
- ADGRL3 | c.412C>T p.P138S (on ENST00000506720 / NM_001322402.2; = p.P70S on NM_015236.6) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV72269117; called by muse, mutect2, varscan2
- ADGRV1 | c.3001G>A p.D1001N | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1203018290, COSV67987928; called by muse, mutect2, varscan2
- AFAP1 | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV61796385; called by muse, mutect2, varscan2
- AFF3 | c.3316C>T p.P1106S | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV57857969; called by muse, varscan2
- AGER | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.109); catalogued as rs1368252277, COSV61247959; called by muse, mutect2, varscan2
- AGO2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 84/167 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs756399814, COSV55048720; called by muse, mutect2, varscan2
- AGRN | c.4381C>T p.R1461W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65069746; called by muse, mutect2, varscan2
- AHNAK2 | c.11587C>T p.Q3863* | Nonsense Mutation (SNP) | VAF 151/253 reads (60%) | catalogued as COSV60918748; called by muse, mutect2, varscan2
- AHNAK2 | c.7475C>T p.S2492L | Missense Mutation (SNP) | VAF 102/448 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1238349733, COSV60918759; called by muse, mutect2, varscan2
- AHSA1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV53632281; called by muse, mutect2, varscan2
- AIFM3 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100104178, COSV59000368; called by muse, mutect2, varscan2
- AIRE | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV52394827; called by muse, mutect2, varscan2
- AK5 | c.379C>T p.P127S (on ENST00000354567 / NM_174858.3; = p.P101S on NM_012093.4) | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV58356170; called by muse, mutect2, varscan2
- AKAP9 | c.6953T>C p.I2318T (on ENST00000359028; = p.I2294T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs756079297, COSV62349519; called by muse, mutect2, varscan2
- AL645922.1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs770315100, COSV54961101; called by muse, mutect2, varscan2
- ALDH2 | c.681+2T>C p.X227_splice | Splice Site (SNP) | VAF 19/34 reads (56%) | catalogued as COSV55668278; called by muse, mutect2, varscan2
- ALDH7A1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as COSV69259492; called by muse, mutect2, varscan2
- ALDOC | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 86/105 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52025046; called by muse, mutect2, varscan2
- ALMS1 | c.12274C>T p.R4092C | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs774888526, COSV52512746; called by muse, mutect2, varscan2
- ALOX12 | c.1038G>A p.W346* | Nonsense Mutation (SNP) | VAF 147/164 reads (90%) | catalogued as COSV52350507; called by muse, mutect2, varscan2
- ALPK2 | c.5716C>T p.H1906Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV100864530, COSV64493994; called by muse, mutect2, varscan2
- ANK1 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs1250457932, COSV55876208; called by muse, mutect2, varscan2
- ANK1 | c.130-1G>A p.X44_splice | Splice Site (SNP) | VAF 49/120 reads (41%) | catalogued as rs1267754855, COSV55884725; called by muse, mutect2, varscan2
- ANK2 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs759644404, COSV52168242; called by mutect2, varscan2
- ANKFN1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV59450715; called by muse, mutect2, varscan2
- ANKRD30A | c.1765A>T p.K589* (on ENST00000611781; = p.K533* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as COSV64613148; called by muse, mutect2, varscan2
- AOX1 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65982291; called by muse, mutect2, varscan2
- APBA1 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55230380; called by muse, mutect2, varscan2
- APH1A | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV52529674; called by muse, mutect2
- APOB | c.8786G>A p.W2929* | Nonsense Mutation (SNP) | VAF 108/150 reads (72%) | catalogued as COSV51940133; called by muse, mutect2, varscan2
- AQP8 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54845861; called by muse, mutect2, varscan2
- ARAP2 | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58288225; called by muse, mutect2, varscan2
- ARFGEF3 | c.5782G>A p.E1928K | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV52460699; called by muse, mutect2, varscan2
- ARHGEF18 | c.492A>G p.E164= (on ENST00000359920 / NM_001130955.2; = p.E60= on NM_015318.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 28/118 reads (24%) | catalogued as COSV60470826; called by muse, mutect2, varscan2
- ARL6 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV60117896; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2
- ARMC5 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51657458; called by muse, mutect2, varscan2
- ARMH4 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV50766306; called by muse, mutect2, varscan2
- ARMH4 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs769362182, COSV50762374, COSV50766343; called by muse, mutect2, varscan2
- ASB5 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs370097719; called by muse, mutect2, varscan2
- ASL | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767023696, COSV59188636, COSV59190049; called by muse, mutect2, varscan2
- ASRGL1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57125118; called by muse, mutect2
- ASTL | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as COSV60904591; called by muse, mutect2, varscan2
- ASXL3 | c.3935C>T p.S1312F | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV99324222; called by muse, mutect2, varscan2
- ATCAY | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV56656997; called by muse, mutect2, varscan2
- ATF3 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 89/107 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1362853658, COSV58378047; called by muse, mutect2, varscan2
- ATF5 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs775228718, COSV61312490; called by muse, mutect2
- ATM | c.3935G>A p.R1312K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV53739061, COSV53751288; called by muse, mutect2, varscan2
- ATMIN | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as rs772805437, COSV55146067; called by muse, mutect2, varscan2
- ATP10A | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1381646630, COSV63519072; called by muse, mutect2, varscan2
- ATP10D | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.348); catalogued as COSV56708881; called by muse, mutect2, varscan2
- ATP1B1 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 74/102 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV63179514; called by muse, mutect2, varscan2
- ATP7B | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV54439894; called by muse, mutect2, varscan2
- ATP8A1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1357805168, COSV100045253, COSV52531376; called by muse, mutect2, varscan2
- B4GALNT1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV57543266; called by muse, mutect2, varscan2
- BCAN | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 115/166 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61257536; called by muse, mutect2, varscan2
- BCL11B | c.2170G>A p.D724N (on ENST00000357195 / NM_001282237.2; = p.D653N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV61736423; called by muse, mutect2
- BCL9L | c.2911G>A p.G971R | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV52685524; called by muse, mutect2, varscan2
- BCL9L | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as COSV58313818; called by muse, mutect2, varscan2
- BCS1L | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV55308093; called by muse, mutect2, varscan2
- BEST2 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV50367913, COSV99244647; called by muse, mutect2, varscan2
- BICD1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV55681452; called by muse, mutect2, varscan2
- BICD1 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1009886917, COSV55681459; called by muse, mutect2, varscan2
- BICD2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV100794059; called by muse, mutect2, varscan2
- BICDL1 | c.802C>A p.R268S | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV66907007, COSV66908132; called by muse, mutect2, varscan2
- BIRC6 | c.13070C>T p.P4357L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70201177; called by muse, mutect2, varscan2
- BLNK | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56411918; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BPIFB6 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 151/291 reads (52%) | catalogued as COSV62755621; called by muse, mutect2, varscan2
- BTN3A3 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV55072444; called by muse, mutect2
- C10orf71 | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1173747536, COSV100110008; called by muse, mutect2, varscan2
- C19orf18 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs150585544; called by muse, mutect2, varscan2
- C19orf18 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV100071713; called by muse, mutect2, varscan2
- C1S | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1555162895, COSV61071250; called by muse, mutect2, varscan2
- C1orf50 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs1557585687, COSV65308258; called by muse, mutect2, varscan2
- C3orf20 | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.165); catalogued as COSV53786317; called by muse, mutect2, varscan2
- C5 | c.4426C>G p.R1476G | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as CM950186, COSV56328799; called by muse, mutect2, varscan2
- C6 | c.1903C>T p.L635F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.298); catalogued as COSV54712066; called by muse, mutect2, varscan2
- C8A | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as COSV63483130; called by muse, mutect2, varscan2
- CA14 | c.723G>T p.L241= | Splice Region (SNP) | VAF 14/127 reads (11%) | catalogued as COSV52529668; called by muse, mutect2, varscan2
- CACNA1C | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59733195, COSV59740528; called by muse, mutect2, varscan2
- CACNA1E | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 87/118 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1468245846, COSV62390167; called by muse, mutect2, varscan2
- CACNA1H | c.4496T>G p.V1499G | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61993962; called by muse, mutect2, varscan2
- CACNA1I | c.4196C>T p.P1399L | Missense Mutation (SNP) | VAF 115/296 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60811358; called by muse, mutect2, varscan2
- CACNA1S | c.4513C>A p.L1505I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62940809; called by muse, mutect2, varscan2
- CACNA2D4 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54952294; called by muse, mutect2, varscan2
- CACNA2D4 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs769056546, COSV54952306; called by muse, mutect2, varscan2
- CALML6 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57069775; called by muse, mutect2, varscan2
- CAMTA1 | c.4951C>T p.R1651C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438611747, COSV57907281; called by muse, mutect2
- CAPN12 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61016780; called by muse, mutect2, varscan2
- CAPN3 | c.2029C>T p.L677F | Missense Mutation (SNP) | VAF 87/110 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV55517921; called by muse, mutect2, varscan2
- CAPN6 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0.304); catalogued as COSV60695514; called by muse, mutect2, varscan2
- CASR | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV56136810; called by muse, mutect2, varscan2
- CCDC74B | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV60102607; called by muse, mutect2, varscan2
- CCDC85A | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs765502186, COSV101339350, COSV68149842; called by muse, mutect2, varscan2
- CCDC88B | c.2124delinsTT p.Q709Sfs*34 | Frame Shift Ins (INS) | VAF 11/37 reads (30%) | catalogued as COSV57267326; called by mutect2*, pindel, varscan2*
- CCDC9 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs774665624, COSV55719473; called by muse, mutect2, varscan2
- CCN4 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as rs1438543879, COSV51531476, COSV51532907; called by muse, mutect2, varscan2
- CCR5 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV99433306; called by mutect2, varscan2
- CCR8 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58337484; called by muse, mutect2, varscan2
- CCT8L2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63462861; called by muse, mutect2, varscan2
- CD163L1 | c.1933A>T p.I645F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58018354; called by muse, mutect2, varscan2
- CD1E | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.283); catalogued as COSV63771428; called by muse, mutect2, varscan2
- CD300A | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60410386; called by muse, mutect2, varscan2
- CD33 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.053); catalogued as COSV51802473; called by muse, mutect2, varscan2
- CD6 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV57839798; called by muse, mutect2, varscan2
- CD96 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV51917943; called by muse, mutect2, varscan2
- CDC14B | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV55787103; called by muse, mutect2, varscan2
- CDC42BPA | c.3371C>T p.S1124F (on ENST00000334218 / NM_001366019.2; = p.S1111F on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV100504468; called by muse, mutect2, varscan2
- CDC42BPB | c.3715C>T p.L1239F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as rs765283166, COSV63475457; called by muse, mutect2, varscan2
- CDCP1 | c.779T>A p.L260Q | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV56106186; called by muse, mutect2, varscan2
- CDH16 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.551); catalogued as rs532055028, COSV100234390, COSV55337326; called by muse, mutect2, varscan2
- CDH18 | c.2131G>T p.D711Y | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.485); catalogued as COSV56931642; called by muse, mutect2, varscan2
- CDH23 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54939253, COSV99821796; called by muse, mutect2, varscan2
- CDH5 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs376592116, COSV58518143; called by muse, mutect2, varscan2
- CDH8 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs918412102, COSV54875163; called by muse, mutect2, varscan2
- CEACAM18 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781386851, COSV67283250; called by muse, mutect2, varscan2
- CELSR2 | c.7541C>T p.S2514F | Missense Mutation (SNP) | VAF 57/390 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54774084; called by muse, mutect2, varscan2
- CEP350 | c.4663C>T p.P1555S | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV62604458; called by muse, mutect2, varscan2
- CEP72 | c.1265T>G p.L422R | Missense Mutation (SNP) | VAF 94/105 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV53793856; called by muse, mutect2, varscan2
- CEP97 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV59125325; called by muse, mutect2, varscan2
- CES3 | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV57594053; called by muse, mutect2, varscan2
- CFAP221 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54655755; called by muse, mutect2, varscan2
- CFAP61 | c.2627G>C p.C876S | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV55634038; called by muse, mutect2, varscan2
- CFAP91 | c.1202-1G>A p.X401_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV56341964; called by muse, mutect2, varscan2
- CGNL1 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV55570002; called by muse, mutect2, varscan2
- CHAMP1 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV63522614; called by muse, mutect2, varscan2
- CHD3 | c.2484G>T p.E828D | Missense Mutation (SNP) | VAF 133/163 reads (82%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV57876617; called by muse, mutect2, varscan2
- CHD8 | c.3785C>T p.S1262F (on ENST00000646647 / NM_001170629.2; = p.S983F on NM_020920.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67871220; called by muse, mutect2
- CHEK2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs777588170, COSV60421845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHGA | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV53663558; called by muse, mutect2
- CHPF2 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs909196590, COSV50392644; called by muse, mutect2, varscan2
- CHRM3 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382696054, COSV55089720; called by muse, mutect2, varscan2
- CIDEA | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57598879; called by muse, mutect2, varscan2
- CLN5 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV66284379; called by muse, mutect2, varscan2
- CLU | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs375198703; called by muse, mutect2, varscan2
- CNOT9 | c.262A>T p.N88Y | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55300399; called by muse, mutect2, varscan2
- CNTN6 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs267599602, COSV63176573; called by muse, mutect2, varscan2
- CNTN6 | c.2818-1G>A p.X940_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV63176578; called by muse, mutect2, varscan2
- COL15A1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV66642760; called by muse, mutect2, varscan2
- COL18A1 | c.1982G>A p.G661E (on ENST00000359759 / NM_130444.3; = p.G426E on NM_030582.4) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs1384628943, COSV62703015; called by mutect2, varscan2
- COL19A1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100507461, COSV59576680; called by muse, mutect2, varscan2
- COL26A1 | c.962C>T p.P321L (on ENST00000313669 / NM_001278563.3; = p.P319L on NM_133457.4) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.651); catalogued as rs755771940, COSV100561627; called by muse, mutect2, varscan2
- COL4A2 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64629689; called by muse, mutect2, varscan2
- COL5A1 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 83/127 reads (65%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV65666502; called by muse, mutect2, varscan2
- COL5A3 | c.2768G>A p.G923E | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53412934; called by muse, mutect2, varscan2
- COL6A1 | c.2995G>T p.G999C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62613848; called by muse, mutect2, varscan2
- COL6A6 | c.5028G>A p.K1676= | Splice Region (SNP) | VAF 3/15 reads (20%) | catalogued as COSV62028289; called by muse, mutect2
- COL8A1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs754505017, COSV53736321; called by muse, mutect2, varscan2
- COMMD5 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs759200985, COSV57384134; called by muse, mutect2, varscan2
- COQ9 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as rs1327256293, COSV52646189; called by muse, mutect2, varscan2
- CORO7 | c.1689T>C p.A563= | Splice Region (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99227453; called by muse, mutect2, varscan2
- CORO7 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV99227455; called by muse, mutect2, varscan2
- CPA3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56045717; called by muse, mutect2, varscan2
- CRACDL | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967032367, COSV67408722; called by muse, mutect2, varscan2
- CSAD | c.146C>T p.P49L (on ENST00000444623 / NM_001244705.2; = p.P76L on NM_015989.5) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57243531; called by muse, mutect2, varscan2
- CSF2RB | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV53258618; called by muse, mutect2, varscan2
- CSMD1 | c.8023C>T p.R2675* (on ENST00000520002; = p.R2674* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 106/234 reads (45%) | catalogued as COSV59338572; called by muse, mutect2, varscan2
- CSMD1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs922879963, COSV68218874; called by muse, mutect2, varscan2
- CSMD2 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV53923819; called by muse, mutect2, varscan2
- CSMD3 | c.3671G>A p.G1224D (on ENST00000297405 / NM_001363185.1; = p.G1120D on NM_052900.3) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52214401; called by muse, mutect2, varscan2
- CSMD3 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52110518, COSV99033799; called by muse, mutect2
- CTAGE6 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV101417830; called by muse, mutect2, varscan2
- CTDSPL2 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV52946800; called by muse, mutect2, varscan2
- CTNNA2 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV63576919; called by muse, mutect2, varscan2
- CTR9 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV63728901; called by muse, mutect2, varscan2
- CTRL | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.054); catalogued as COSV52123876; called by muse, mutect2, varscan2
- CYP4F8 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1265530862, COSV57854421; called by muse, mutect2, varscan2
- CYTIP | c.549A>T p.Q183H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV51634252; called by muse, mutect2, varscan2
- DACT1 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60021481; called by muse, mutect2, varscan2
- DBH | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55041476; called by muse, mutect2, varscan2
- DBX2 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs748293885, COSV60338174; called by muse, mutect2, varscan2
- DCANP1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs376193776; called by muse, varscan2
- DCC | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59110329; called by muse, mutect2, varscan2
- DDX20 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1557924414, COSV63779750; called by muse, mutect2, varscan2
- DDX60L | c.4199C>T p.S1400F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52709522; called by muse, mutect2, varscan2
- DEFB104A | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765448437, COSV100055372; called by mutect2, varscan2
- DEFB110 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV67018111; called by muse, mutect2, varscan2
- DEPDC5 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56700912; called by muse, mutect2, varscan2
- DEPDC5 | c.2251C>T p.P751S (on ENST00000400246; = p.P820S on NM_014662.5) | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.413); catalogued as COSV56700948; called by muse, mutect2, varscan2
- DGKD | c.566C>T p.S189L (on ENST00000264057 / NM_152879.3; = p.S145L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/142 reads (72%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs1325916707, COSV51057863; called by muse, mutect2, varscan2
- DHX15 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV61027625; called by muse, mutect2, varscan2
- DHX32 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 72/88 reads (82%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.191); catalogued as COSV52941054; called by muse, mutect2, varscan2
- DLG2 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54655615; called by muse, mutect2, varscan2
- DLK2 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769739853, COSV55089390; called by muse, mutect2, varscan2
- DMBT1 | c.3643G>A p.E1215K (on ENST00000338354 / NM_001377530.1; = p.E716K on NM_004406.3) | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100351956; called by mutect2, varscan2
- DMD | c.9514C>T p.P3172S | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626696; called by muse, mutect2, varscan2
- DMKN | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV100303458; called by muse, mutect2, varscan2
- DNAH12 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60857355; called by muse, mutect2, varscan2
- DNAH17 | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs763243487, COSV67756875; called by muse, mutect2, varscan2
- DNAH17 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV67756880; called by muse, mutect2, varscan2
- DNAH3 | c.9088G>A p.D3030N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54529423; called by muse, mutect2, varscan2
- DNAH5 | c.1593G>A p.M531I | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1216204013, COSV54225871; called by muse, mutect2, varscan2
- DNAH8 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV59445112, COSV59455903; called by muse, mutect2, varscan2
- DNAH8 | c.3455G>A p.R1152K | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59426646, COSV59430763; called by muse, mutect2, varscan2
- DNAH8 | c.6482C>T p.A2161V | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59455958; called by muse, mutect2, varscan2
- DNAI4 | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs529847626, COSV64021314; called by muse, mutect2, varscan2
- DNAJB12 | c.514C>T p.H172Y (on ENST00000338820; = p.H138Y on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58760707; called by muse, mutect2, varscan2
- DOCK8 | c.6121G>A p.E2041K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66620975; called by muse, mutect2, varscan2
- DOCK9 | c.3394C>T p.R1132C (on ENST00000376460 / NM_001366676.2; = p.R1133C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV59633133; called by muse, mutect2, varscan2
- DPPA2 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV72118141; called by muse, mutect2, varscan2
- DPYD | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 89/117 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411615618, COSV60079754; called by muse, mutect2, varscan2
- DPYS | c.1337T>A p.V446E | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100679473; called by muse, mutect2, varscan2
- DPYS | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100679474; called by muse, mutect2, varscan2
- DSCAM | c.4880G>A p.R1627K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV68029348; called by muse, mutect2, varscan2
- DSCAML1 | c.2969C>T p.S990F (on ENST00000321322; = p.S930F on NM_020693.4) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1465069433, COSV58394347; called by muse, mutect2, varscan2
- DSG4 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57393130; called by muse, mutect2, varscan2
- DSP | c.7144G>A p.E2382K | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV65792798; called by muse, mutect2, varscan2
- DUSP11 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55594930; called by muse, mutect2, varscan2
- DUXA | c.544+1G>A p.X182_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as rs532749484, COSV73729755; called by muse, mutect2, varscan2
- DYNC1H1 | c.4094C>T p.A1365V | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV64138229; called by muse, mutect2, varscan2
- ECH1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV55489484; called by muse, mutect2, varscan2
- ECRG4 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52999964, COSV53001653; called by muse, mutect2, varscan2
- EDN3 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.113); catalogued as COSV61107226; called by muse, mutect2, varscan2
- EDNRB | c.898A>G p.K300E (on ENST00000377211 / NM_001201397.1; = p.K210E on NM_000115.5) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV57524489; called by muse, mutect2, varscan2
- EFCAB6 | c.3002C>T p.T1001I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV99413048; called by muse, mutect2, varscan2
- EIF2S3 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as COSV99450788; called by muse, mutect2, varscan2
- EIF2S3 | c.1133T>A p.L378H | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99450790; called by muse, mutect2, varscan2
- ELF5 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.085); catalogued as COSV56629241; called by muse, mutect2, varscan2
- ELP1 | c.3031C>T p.R1011C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs763981711, COSV65896384; called by muse, mutect2
- ENAM | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV68536246; called by muse, mutect2, varscan2
- ENPP5 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs756651686, COSV57909055; called by muse, mutect2, varscan2
- EP400 | c.3316C>T p.P1106S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57775880; called by muse, varscan2
- EPB41L4B | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.51); catalogued as COSV65797413; called by muse, mutect2, varscan2
- EPHA10 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778467077, COSV57624752; called by muse, mutect2, varscan2
- EPPK1 | c.4705G>A p.G1569R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554659993, COSV73261549; called by muse, mutect2, varscan2
- ERBB3 | c.3533C>T p.S1178F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV57256276; called by muse, mutect2, varscan2
- ERICH3 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 101/137 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs865943394, COSV58604950; called by muse, mutect2, varscan2
- ERN2 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs867067714, COSV56834781; called by muse, mutect2, varscan2
- ERVW-1 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV71259462; called by muse, mutect2, varscan2
- ESPL1 | c.4918C>T p.L1640F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV57760125; called by muse, mutect2, varscan2
- ESRRB | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs757736226, COSV55062957, COSV99834957; called by muse, mutect2, varscan2
- ESS2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52817318; called by muse, mutect2, varscan2
- EVC2 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60395810; called by muse, mutect2, varscan2
- EVL | c.710G>A p.R237Q (on ENST00000402714 / NM_001330221.2; = p.R239Q on NM_016337.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV67375883; called by muse, mutect2, varscan2
- EXT2 | c.964C>T p.R322C (on ENST00000343631; = p.R355C on NM_000401.3) | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749297206, COSV59151319; called by muse, mutect2, varscan2
- EZR | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV61454302; called by muse, mutect2, varscan2
- EZR | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61453816; called by muse, mutect2, varscan2
- FAM124A | c.766C>T p.P256S (on ENST00000322475 / NM_001242312.2; = p.P292S on NM_145019.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV54477461; called by muse, mutect2, varscan2
- FAM135B | c.3771C>A p.N1257K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52733087; called by muse, mutect2, varscan2
- FAM135B | c.3413G>A p.G1138E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52733125, COSV52755434; called by muse, mutect2, varscan2
- FAM13C | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV53250625; called by muse, mutect2, varscan2
- FAM189A2 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.08); catalogued as COSV57384700; called by muse, mutect2, varscan2
- FAM214A | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV55925132; called by muse, mutect2, varscan2
- FAM221B | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV65074594; called by muse, mutect2, varscan2
- FAM83B | c.2878C>T p.R960C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs145623856; called by muse, mutect2, varscan2
- FAM90A1 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | catalogued as rs765702576, COSV56712823; called by muse, mutect2, varscan2
- FANCM | c.5594G>A p.R1865K | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57502479; called by muse, mutect2, varscan2
- FAT2 | c.4654C>T p.P1552S | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV55822373, COSV99942326; called by muse, mutect2, varscan2
- FAT3 | c.4384C>T p.Q1462* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV53128098; called by muse, mutect2, varscan2
- FBN3 | c.7798G>A p.D2600N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.241); catalogued as COSV54463954; called by muse, mutect2, varscan2
- FBN3 | c.5576G>A p.G1859E | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54463966; called by muse, mutect2, varscan2
- FCGR1A | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV64985661; called by muse, mutect2, varscan2
- FCHO1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53183162; called by muse, mutect2, varscan2
- FER1L6 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV67548784; called by muse, mutect2, varscan2
- FIBIN | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV59413072; called by muse, mutect2, varscan2
- FKBP5 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs773801221, COSV61882138; called by muse, mutect2, varscan2
- FLG | c.11303G>A p.G3768E | Missense Mutation (SNP) | VAF 115/738 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64242615; called by muse, varscan2
- FLNB | c.6851C>T p.S2284F | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.323); catalogued as COSV55883288; called by muse, mutect2, varscan2
- FLRT3 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 90/140 reads (64%) | SIFT tolerated (0.64); PolyPhen benign (0.268); catalogued as rs1294699297, COSV54002106; called by muse, mutect2, varscan2
- FN1 | c.4622-1G>T p.X1541_splice | Splice Site (SNP) | VAF 38/65 reads (58%) | catalogued as COSV60555686; called by muse, mutect2, varscan2
- FNDC1 | c.5203C>T p.P1735S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51940537; called by muse, mutect2, varscan2
- FNDC3A | c.3100C>T p.L1034F (on ENST00000492622 / NM_001079673.2; = p.L978F on NM_014923.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68133801; called by muse, mutect2, varscan2
- FOXN2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 124/175 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61318642; called by muse, mutect2, varscan2
- FOXO1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1034299550, COSV65425761; called by muse, mutect2, varscan2
- FRAS1 | c.6398G>A p.G2133D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53620120; called by muse, mutect2, varscan2
- FRAS1 | c.11649G>A p.M3883I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV53620144; called by muse, mutect2
- FSCB | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV100469332, COSV61218576; called by muse, mutect2, varscan2
- FTCD | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV52426540, COSV52430799; called by muse, mutect2, varscan2
- FUT3 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs371816472; called by muse, mutect2, varscan2
- FUT9 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.086); catalogued as COSV56149585; called by muse, mutect2, varscan2
- GAP43 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV59345252; called by muse, mutect2, varscan2
- GBA3 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72438265; called by muse, mutect2, varscan2
- GBF1 | c.3523G>A p.V1175M (on ENST00000369983 / NM_001377137.1; = p.V1174M on NM_004193.3) | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as COSV64146059, COSV64149182; called by muse, mutect2, varscan2
- GCG | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as rs762656543, COSV64961619; called by muse, mutect2, varscan2
- GIMAP2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV56235581; called by muse, mutect2, varscan2
- GJA10 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65355408; called by muse, mutect2, varscan2
- GJA10 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257526011, COSV65355075; called by muse, mutect2, varscan2
- GLDC | c.2002G>T p.V668L | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs766743130, COSV58681300; called by muse, mutect2, varscan2
- GLI2 | c.1436G>A p.R479Q (on ENST00000361492 / NM_001374353.1; = p.R496Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1413032761, COSV58044507; called by muse, varscan2
- GLMN | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 122/167 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV64860784; called by muse, mutect2, varscan2
- GLYAT | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV53539670, COSV53541023; called by muse, mutect2, varscan2
- GON4L | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55195949; called by muse, mutect2, varscan2
- GON4L | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55195973; called by muse, mutect2, varscan2
- GON4L | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 75/99 reads (76%) | catalogued as COSV55195997; called by muse, mutect2, varscan2
- GPAM | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV62081466; called by muse, mutect2, varscan2
- GPN2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.41); catalogued as COSV65129221; called by muse, mutect2, varscan2
- GPR156 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV59940663; called by muse, mutect2, varscan2
- GPR182 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV55626390; called by muse, mutect2, varscan2
- GPR39 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); catalogued as rs1182398835, COSV61424624; called by muse, mutect2, varscan2
- GPR65 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 91/147 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV50863077; called by muse, mutect2, varscan2
- GPRC6A | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1357846457, COSV59953723; called by muse, mutect2, varscan2
- GPT2 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV60839160; called by muse, mutect2, varscan2
- GRIA1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV53608602; called by muse, mutect2, varscan2
- GRID2 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); catalogued as COSV56220772; called by muse, mutect2
- GRIN2B | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1383833874, COSV74205659, COSV74206438; called by muse, mutect2, varscan2
- GRIN2D | c.2150C>T p.S717F | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616235; called by muse, mutect2, varscan2
- GRM3 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.997); catalogued as COSV64473973; called by muse, mutect2, varscan2
- GRM6 | c.2372C>T p.T791I | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99179536; called by muse, mutect2, varscan2
- GRM7 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs752652087, COSV63142159, COSV63148872; called by muse, mutect2, varscan2
- GUCY2C | c.2765G>A p.G922E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53791432; called by muse, mutect2, varscan2
- GYPB | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs749614403, COSV51626990; called by muse, mutect2, varscan2
- GYPE | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV62262521; called by muse, mutect2, varscan2
- HACE1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53503681; called by muse, mutect2, varscan2
- HCFC1 | c.5687C>T p.A1896V | Missense Mutation (SNP) | VAF 103/115 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60073746; called by muse, mutect2, varscan2
- HCN1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 86/101 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57517620; called by muse, mutect2, varscan2
- HECTD4 | c.7507C>T p.P2503S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.999); catalogued as COSV66393963; called by muse, mutect2, varscan2
- HECW1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV67830993; called by muse, mutect2, varscan2
- HECW2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53663268; called by muse, mutect2, varscan2
- HEG1 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV60762983; called by muse, mutect2, varscan2
- HELQ | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV55025787; called by muse, mutect2, varscan2
- HIF3A | c.244G>A p.G82R (on ENST00000377670 / NM_152795.4; = p.G80R on NM_152794.4) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.276); catalogued as rs755833063, COSV52200087; called by muse, mutect2, varscan2
- HIP1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1184904694, COSV61187549; called by muse, mutect2, varscan2
- HIVEP2 | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as COSV50019417; called by muse, mutect2, varscan2
- HIVEP3 | c.5000C>T p.A1667V | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.723); catalogued as COSV56017361; called by muse, mutect2, varscan2
- HKDC1 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1201295597, COSV63577693; called by muse, mutect2, varscan2
- HMCN1 | c.14420A>G p.N4807S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV54906660; called by muse, mutect2, varscan2
- HNF4G | c.-23-1G>A | Splice Site (SNP) | VAF 21/47 reads (45%) | catalogued as COSV62969822; called by muse, mutect2, varscan2
- HNMT | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV54508497; called by muse, mutect2, varscan2
- HOATZ | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs771451441, COSV60441684; called by muse, mutect2, varscan2
- HOXA5 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs745560377, COSV56072137; called by muse, mutect2, varscan2
- HRC | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.227); catalogued as rs778475642, COSV53257044; called by muse, mutect2, varscan2
- HSD17B2 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV52276731; called by muse, mutect2, varscan2
- HTR3C | c.1236G>A p.M412I | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV59176186; called by muse, mutect2, varscan2
- HTT | c.6724C>T p.P2242S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV61864064; called by muse, mutect2, varscan2
- HYDIN | c.7756G>A p.E2586K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as COSV59260683; called by muse, varscan2
- IDO2 | c.488G>A p.S163N (on ENST00000389060; = p.S176N on NM_194294.2) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV58426403; called by muse, mutect2, varscan2
- IFI44 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV66074995; called by muse, mutect2, varscan2
- IFNL3 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV69830045; called by muse, mutect2, varscan2
- IGFN1 | c.1939C>T p.P647S (on ENST00000295591 / NM_001367841.1; = p.P3104S on NM_001164586.2) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1462734532, COSV99811835; called by muse, mutect2, varscan2
- IGHV3-30 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs746166672; called by muse, mutect2, varscan2
- IL1RAPL2 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 61/70 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61146324; called by muse, mutect2, varscan2
- IL2RB | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765304134, COSV53426917; called by muse, mutect2, varscan2
- IL4R | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV50148361; called by muse, mutect2, varscan2
- IMPG1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs774566521, COSV63113184; called by muse, mutect2, varscan2
- INHBA | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54221739; called by muse, mutect2, varscan2
- INPP5D | c.3080C>T p.S1027F (on ENST00000445964 / NM_001017915.3; = p.S1026F on NM_005541.5) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV64035505; called by muse, mutect2, varscan2
- INTS7 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV65344517; called by muse, mutect2, varscan2
- IPPK | c.1108T>C p.Y370H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55334432; called by muse, mutect2, varscan2
- IRGC | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs764738059, COSV54983200, COSV54983936; called by muse, mutect2, varscan2
- ISM2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 87/142 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV53635651; called by muse, mutect2, varscan2
- ITGA10 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65197881; called by muse, mutect2, varscan2
- ITGA5 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53218632; called by muse, mutect2, varscan2
- ITGAD | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV66758184; called by muse, mutect2, varscan2
- ITGAX | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1567304830, COSV51647061; called by muse, mutect2, varscan2
- ITGAX | c.3104C>T p.P1035L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1408202328, COSV51647071; called by muse, mutect2, varscan2
- ITGB4 | c.3152G>A p.G1051E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as rs528647078, COSV99563803; called by muse, mutect2, varscan2
- ITPA | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1329748108, COSV101200058; ClinVar: uncertain significance; called by muse, varscan2
- ITPKB | c.2584C>T p.R862* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV55263820; called by muse, mutect2, varscan2
- ITPR3 | c.5597C>T p.S1866F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as COSV65411037; called by muse, mutect2, varscan2
- JAKMIP1 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs759983342, COSV51545250, COSV99290558; called by muse, mutect2
- JAML | c.379T>A p.F127I (on ENST00000356289 / NM_001098526.2; = p.F117I on NM_153206.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99409393; called by muse, mutect2, varscan2
- KALRN | c.3359C>T p.T1120I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53768984; called by muse, mutect2, varscan2
- KCNA10 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63904817; called by muse, mutect2, varscan2
- KCNH1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55087341; called by muse, mutect2, varscan2
- KCNH4 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 71/82 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52917948; called by muse, mutect2, varscan2
- KCNJ8 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV53716880; called by muse, mutect2, varscan2
- KCNQ5 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59665918; called by muse, mutect2, varscan2
- KIAA1217 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 31/43 reads (72%) | catalogued as COSV56818381; called by muse, mutect2, varscan2
- KIAA1755 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54077554; called by muse, mutect2, varscan2
- KIF1A | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57492822; called by muse, mutect2, varscan2
- KLF12 | c.1171C>T p.H391Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66574880; called by muse, mutect2, varscan2
- KLHDC8A | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as rs747924188, COSV65678961; called by muse, mutect2, varscan2
- KLK14 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.665); catalogued as rs1024820222, COSV50069026; called by muse, mutect2, varscan2
- KLK7 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV58344400; called by muse, mutect2, varscan2
- KPNA5 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV62652958; called by muse, mutect2
- KPRP | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as COSV64221991; called by muse, mutect2, varscan2
- KRBA1 | c.2927C>T p.P976L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.81); catalogued as COSV55442166; called by muse, mutect2
- KRT81 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV59810321; called by muse, mutect2, varscan2
- KRTAP10-4 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV59967165; called by muse, mutect2, varscan2
- KRTAP10-7 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs376631519; called by muse, varscan2
- LAMA2 | c.6992+2T>C p.X2331_splice | Splice Site (SNP) | VAF 37/66 reads (56%) | catalogued as COSV70350436; called by muse, mutect2, varscan2
- LARP4 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV53321558; called by muse, mutect2, varscan2
- LCOR | c.3116C>T p.S1039L | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.17); PolyPhen benign (0.207); catalogued as rs1369182144, COSV53716671; called by muse, mutect2, varscan2
- LCT | c.4205G>A p.G1402E | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99929101; called by muse, mutect2, varscan2
- LCT | c.4204G>A p.G1402R | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV51548868, COSV99929103; called by muse, mutect2, varscan2
- LCT | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370971797; called by muse, mutect2, varscan2
- LEPR | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60757367; called by muse, mutect2, varscan2
- LEPR | c.2601G>A p.M867I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60750358, COSV60757388; called by muse, mutect2, varscan2
- LGR5 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV57002317; called by muse, mutect2, varscan2
- LGR6 | c.1841C>T p.S614F (on ENST00000367278 / NM_001017403.1; = p.S562F on NM_021636.3) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.864); catalogued as COSV55153173; called by muse, mutect2, varscan2
- LGSN | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs749286541, COSV65727549; called by muse, varscan2
- LHX9 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV61329506; called by muse, mutect2, varscan2
- LIMCH1 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58287195; called by muse, mutect2, varscan2
- LIPF | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as rs770032747, COSV53284663; called by muse, mutect2, varscan2
- LIPN | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1161760546, COSV68384123; called by muse, mutect2, varscan2
- LIX1L | c.597+1G>T p.X199_splice | Splice Site (SNP) | VAF 18/92 reads (20%) | catalogued as rs781903861, COSV63417146; called by muse, mutect2, varscan2
- LMO7 | c.2471C>T p.P824L (on ENST00000357063; = p.P505L on NM_005358.5) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1404237287, COSV58539855; called by muse, mutect2, varscan2
- LNPEP | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV51478724; called by muse, mutect2, varscan2
- LOXL2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV66690842; called by muse, mutect2, varscan2
- LPA | c.4123G>A p.E1375K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs866955401, COSV60303981; called by muse, mutect2, varscan2
- LPIN1 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs113391634, COSV56769707; called by muse, mutect2, varscan2
- LPL | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60931532; called by muse, mutect2, varscan2
- LRFN4 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58921949; called by muse, mutect2, varscan2
- LRRC1 | c.952A>C p.N318H | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63829590; called by muse, mutect2, varscan2
- LRRC32 | c.1186A>G p.N396D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52633613; called by muse, mutect2, varscan2
- LRRC41 | c.357+1G>A p.X119_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | catalogued as COSV58440541; called by muse, mutect2, varscan2
- LRRC74A | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV53610441; called by muse, varscan2
- LSM10 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 82/105 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV59872430; called by muse, mutect2, varscan2
- LYRM7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/11 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs531275086, COSV65086567; called by muse, mutect2, varscan2
- MACF1 | c.2693C>T p.S898F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV58380576; called by muse, mutect2, varscan2
- MADD | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV60625492; called by muse, mutect2, varscan2
- MAGEC1 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 106/116 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV53575204; called by muse, mutect2, varscan2
- MAGEC3 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT tolerated (0.39); PolyPhen benign (0.094); catalogued as rs868717682, COSV68923833; called by muse, mutect2, varscan2
- MAN1C1 | c.636C>T p.F212= | Splice Region (SNP) | VAF 81/113 reads (72%) | catalogued as rs769609026, COSV56046048; called by muse, mutect2, varscan2
- MANEA | c.222G>T p.K74N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100721518, COSV62589897; called by muse, mutect2, varscan2
- MAP1LC3A | c.52+1G>A p.X18_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as rs1250531802, COSV66381785; called by muse, mutect2, varscan2
- MAP3K13 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); catalogued as COSV53990840; called by muse, mutect2, varscan2
- MAP3K21 | c.1961T>A p.L654* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV64041981; called by muse, mutect2, varscan2
- MAP3K5 | c.2752T>G p.C918G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62889915; called by muse, mutect2, varscan2
- MAPKAPK3 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63597738; called by muse, mutect2, varscan2
- MAPKBP1 | c.1238C>T p.S413F (on ENST00000456763 / NM_001128608.2; = p.S407F on NM_014994.3) | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs267604190, COSV52960314; called by muse, mutect2, varscan2
- MARCHF6 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56882874; called by muse, mutect2, varscan2
- MARCO | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as COSV59055470, COSV59059940; called by muse, mutect2
- MARCO | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59055478; called by muse, mutect2, varscan2
- MARK1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1405197953, COSV65068387; called by muse, mutect2, varscan2
- MASP1 | c.1727G>A p.G576E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61827724; called by muse, mutect2, varscan2
- MAST2 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 214/297 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63619102; called by muse, mutect2, varscan2
- MBD4 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs769817977, COSV51444946; called by muse, mutect2, varscan2
- MBL2 | c.303G>A p.P101= | Splice Region (SNP) | VAF 61/78 reads (78%) | catalogued as rs55902142, COSV64758755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCF2L2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as COSV61055587; called by muse, mutect2, varscan2
- MCOLN1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51176800; called by muse, mutect2, varscan2
- MDC1 | c.5771C>T p.S1924F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64525082; called by muse, mutect2, varscan2
- MED12L | c.4267A>G p.T1423A | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as COSV56383344; called by muse, mutect2, varscan2
- MED12L | c.5740C>T p.L1914F | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.378); catalogued as rs761980500, COSV56383351; called by muse, varscan2
- MED8 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 129/173 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV51941406; called by muse, mutect2, varscan2
- MEGF10 | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57251126, COSV99174719; called by muse, mutect2, varscan2
- MET | c.3932C>T p.P1311L | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV100577143; called by muse, mutect2, varscan2
- MET | c.3933C>T p.P1311= | Splice Region (SNP) | VAF 69/140 reads (49%) | catalogued as COSV100577144; called by muse, mutect2, varscan2
- MGAT4C | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749782221, COSV59833060; called by muse, mutect2, varscan2
- MICAL2 | c.3947C>T p.S1316L | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.29); catalogued as rs375248401; called by muse, mutect2, varscan2
- MICAL3 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99260946; called by muse, mutect2, varscan2
- MICALL1 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV99317153; called by muse, mutect2, varscan2
- MINAR1 | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV59583918, COSV59585355; called by muse, mutect2, varscan2
- MMEL1 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 132/194 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56522463; called by muse, mutect2, varscan2
- MMP2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as rs773564814, COSV54600773; called by muse, mutect2, varscan2
- MOGAT3 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs752714401, COSV56175031; called by muse, mutect2, varscan2
- MOV10L1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV53173691; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746240316, COSV56620954; called by muse, mutect2, varscan2
- MRPL21 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375095771; called by muse, mutect2, varscan2
- MSRB3 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs755781844, COSV57592610; called by muse, mutect2, varscan2
- MTMR4 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 128/144 reads (89%) | catalogued as COSV60201229; called by muse, mutect2, varscan2
- MTUS1 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs922381677, COSV50562720; called by muse, mutect2, varscan2
- MUC16 | c.35293C>T p.P11765S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.91); catalogued as rs746293537, COSV101199312; called by muse, mutect2, varscan2
- MUC16 | c.33202G>A p.E11068K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV67474530, COSV67477058; called by muse, mutect2, varscan2
- MUC16 | c.29164G>A p.E9722K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV67473438; called by muse, mutect2, varscan2
- MUC16 | c.27835C>T p.Q9279* | Nonsense Mutation (SNP) | VAF 42/78 reads (54%) | catalogued as COSV67474540; called by muse, mutect2, varscan2
- MUC16 | c.23102C>T p.P7701L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67474548; called by muse, mutect2, varscan2
- MUC16 | c.22529C>T p.T7510I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as COSV67449219; called by muse, mutect2, varscan2
- MUC16 | c.20213G>A p.R6738Q | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67474551; called by muse, mutect2, varscan2
- MUC16 | c.18703C>T p.P6235S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs758672005, COSV67474554; called by muse, mutect2, varscan2
- MUC16 | c.18094C>T p.H6032Y | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.06); catalogued as rs567848891, COSV67474560; called by muse, mutect2, varscan2
- MUC16 | c.4097G>A p.G1366E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV67474565; called by muse, mutect2, varscan2
- MUC4 | c.13189C>T p.P4397S (on ENST00000463781 / NM_018406.7; = p.P161S on NM_004532.6) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.527); catalogued as rs1250656168, COSV57786733; called by muse, mutect2, varscan2
- MXRA5 | c.5948C>T p.S1983F | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277492063, COSV54239198; called by muse, mutect2, varscan2
- MXRA5 | c.5390G>A p.G1797E | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs867779664, COSV54226391; called by muse, mutect2
- MXRA5 | c.5389G>A p.G1797R | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV54253876; called by muse, mutect2
- MYF6 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57352231; called by muse, mutect2, varscan2
- MYH11 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55557377; called by muse, mutect2, varscan2
- MYH13 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 70/87 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV52832513; called by muse, mutect2, varscan2
- MYH3 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as COSV56866403; called by muse, mutect2, varscan2
- MYLK | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV60613343; called by muse, mutect2, varscan2
- MYO16 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51800533; called by muse, mutect2, varscan2
- MYO16 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.546); catalogued as rs372976718, COSV51822578; called by muse, mutect2, varscan2
- MYO1F | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV57796392; called by muse, mutect2, varscan2
- MYO5B | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 115/243 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218772348, COSV53221764; called by muse, mutect2, varscan2
- MYO5C | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 65/77 reads (84%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as COSV55907856; called by muse, mutect2, varscan2
- MYO7B | c.3169C>T p.P1057S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV67348713; called by muse, mutect2, varscan2
- MYOM2 | c.2147G>A p.G716E | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747830355, COSV50724747; called by muse, mutect2, varscan2
- MYOM3 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs559517820, COSV58395510; called by muse, mutect2, varscan2
- MYOM3 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369456651; called by muse, mutect2
- MYSM1 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 120/161 reads (75%) | catalogued as rs747826724, COSV68977684; called by muse, mutect2, varscan2
- NAF1 | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56804734; called by muse, mutect2, varscan2
- NAP1L4 | c.290C>A p.A97E | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.173); catalogued as rs377175684, COSV65881380; called by muse, mutect2, varscan2
- NAT10 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as rs1253347709, COSV57664546; called by muse, mutect2, varscan2
- NCK1 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 41/70 reads (59%) | catalogued as COSV56637997; called by muse, mutect2, varscan2
- NCKAP1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62941701; called by muse, mutect2, varscan2
- NCKAP1L | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53208283, COSV99514764; called by muse, mutect2
- NDST3 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV56621470; called by muse, mutect2, varscan2
- NEB | c.6853G>A p.D2285N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV51427433; called by muse, mutect2
- NELFA | c.1265C>T p.P422L (on ENST00000542778; = p.P411L on NM_005663.5) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs752179327, COSV100373062; called by muse, mutect2, varscan2
- NELFA | c.1264C>T p.P422S (on ENST00000542778; = p.P411S on NM_005663.5) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.341); catalogued as COSV100373065; called by muse, mutect2, varscan2
- NEURL2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99509783; called by muse, mutect2, varscan2
- NEURL2 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs768110929, COSV99509785; called by muse, mutect2, varscan2
- NEUROD1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV99716863; called by muse, mutect2, varscan2
- NFAT5 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.009); catalogued as rs369476982; called by muse, mutect2, varscan2
- NFE2 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56456214; called by muse, mutect2, varscan2
- NGB | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53611610; called by muse, mutect2, varscan2
- NLRP10 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762414203, COSV60778851; called by muse, mutect2, varscan2
- NLRP4 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1328492486, COSV56716201; called by muse, mutect2, varscan2
- NLRP5 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV66764090; called by muse, mutect2, varscan2
- NLRP9 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV60459177; called by muse, mutect2, varscan2
- NOA1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV51737607; called by muse, mutect2, varscan2
- NOMO1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55057282; called by muse, mutect2, varscan2
- NOS1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80348085, COSV57606077; called by muse, mutect2, varscan2
- NOX1 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 80/90 reads (89%) | SIFT tolerated (0.26); PolyPhen benign (0.292); catalogued as COSV54195083; called by muse, mutect2, varscan2
- NPHS1 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1199721527, COSV62288502; called by muse, mutect2, varscan2
- NR1H2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53801108; called by muse, mutect2, varscan2
- NRXN1 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58463010; called by muse, mutect2, varscan2
- NRXN3 | c.917C>T p.S306L (on ENST00000557594 / NM_001272020.2; = p.S938L on NM_004796.6) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1395820246, COSV55334014; called by muse, mutect2, varscan2
- NSMAF | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs768994849, COSV50690042; called by muse, mutect2, varscan2
- NTN4 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs200517574, COSV59218693; called by muse, mutect2, varscan2
- NUMA1 | c.5653C>T p.R1885C | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs745625793, COSV52621402; called by muse, mutect2, varscan2
- NUP98 | c.4402C>T p.P1468S (on ENST00000359171 / NM_001365126.1; = p.P1451S on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61432366; called by muse, mutect2, varscan2
- NYNRIN | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs1298258264, COSV66840983; called by muse, mutect2, varscan2
- OBSCN | c.14384C>T p.T4795I | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52786620; called by muse, mutect2, varscan2
- OCLN | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 26/32 reads (81%) | catalogued as rs750583958, COSV62284935; called by muse, mutect2, varscan2
- ODAM | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV68573011, COSV68573224; called by muse, mutect2, varscan2
- OGG1 | c.466A>T p.T156S | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.129); catalogued as COSV100115266; called by muse, mutect2, varscan2
- OGG1 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100115267; called by muse, mutect2, varscan2
- OLFML3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs769781747, COSV57436115; called by muse, mutect2, varscan2
- OPCML | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); catalogued as COSV100103378, COSV59430487; called by muse, mutect2, varscan2
- OR10G9 | c.306T>A p.F102L | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100901550; called by muse, mutect2, varscan2
- OR11H6 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs367798181; called by muse, mutect2, varscan2
- OR12D3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs760362736, COSV65828517; called by muse, mutect2, varscan2
- OR13C4 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV52927102, COSV52928603; called by muse, mutect2, varscan2
- OR13G1 | c.457T>G p.S153A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV62944503; called by muse, mutect2, varscan2
- OR1B1 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.474); catalogued as COSV100506451, COSV59171900; called by muse, mutect2, varscan2
- OR1C1 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV68715867; called by muse, mutect2, varscan2
- OR1G1 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV100187555, COSV61030079; called by muse, mutect2, varscan2
- OR1L1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV100542114; called by muse, mutect2, varscan2
- OR2A2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68871826; called by muse, mutect2, varscan2
- OR2B6 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376301628; called by muse, mutect2, varscan2
- OR2G2 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV60740922; called by muse, mutect2, varscan2
- OR2L13 | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 62/85 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as COSV63554972; called by muse, mutect2, varscan2
- OR4A16 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 78/135 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as rs1389734335, COSV59041785; called by muse, mutect2, varscan2
- OR4C13 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV73648600; called by muse, mutect2, varscan2
- OR4D5 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58307642; called by muse, mutect2, varscan2
- OR4K1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs779313242, COSV53458864; called by muse, mutect2, varscan2
- OR4Q3 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100057465, COSV59179085; called by muse, mutect2, varscan2
- OR52B4 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs267602877, COSV68768715; called by muse, mutect2, varscan2
- OR56A3 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs781614186, COSV61569381; called by muse, mutect2, varscan2
- OR5AK2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58804699; called by muse, mutect2, varscan2
- OR5B12 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV56905407; called by muse, mutect2, varscan2
- OR5I1 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs200048769, COSV100041741; called by muse, mutect2, varscan2
- OR6X1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV100020534, COSV60009964; called by muse, mutect2, varscan2
- OR7G1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV53317979; called by muse, mutect2, varscan2
- OR8J3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV104399236, COSV56881243; called by muse, mutect2, varscan2
- OXR1 | c.1360C>T p.L454F (on ENST00000442977 / NM_001198532.1; = p.L453F on NM_018002.3) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.149); catalogued as COSV56331060; called by muse, mutect2, varscan2
- P3H2 | c.1453G>A p.G485R | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs754236871, COSV60023161; called by muse, mutect2, varscan2
- P3H4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58637203; called by muse, mutect2, varscan2
- PABPC1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs753302028, COSV59403030; called by muse, mutect2, varscan2
- PACS1 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 90/153 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV57698256; called by muse, mutect2, varscan2
- PADI1 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 78/97 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV64934746; called by muse, mutect2, varscan2
- PADI2 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.651); catalogued as COSV64954060; called by muse, mutect2, varscan2
- PAF1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55394788; called by muse, mutect2, varscan2
- PAPPA | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV60285997; called by muse, mutect2, varscan2
- PAPPA2 | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 102/159 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751035399, COSV62777854; called by muse, mutect2, varscan2
- PARP12 | c.1862G>T p.R621L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.46); catalogued as COSV54932779; called by muse, mutect2, varscan2
- PARVB | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); catalogued as COSV100114578, COSV58688033, COSV58692157; called by muse, mutect2, varscan2
- PC | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.275); catalogued as COSV58921927; called by muse, mutect2, varscan2
- PCARE | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 94/126 reads (75%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV59055549; called by muse, mutect2, varscan2
- PCDH18 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61269430; called by muse, mutect2, varscan2
- PCDHA3 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 76/97 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as rs528768034, COSV63542826; called by muse, mutect2, varscan2
- PCDHA5 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.187); catalogued as COSV65352069; called by muse, mutect2, varscan2
- PCDHB7 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50778824; called by muse, mutect2, varscan2
- PCLO | c.5191C>T p.P1731S | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61642904; called by muse, mutect2, varscan2
- PCLO | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100430299; called by mutect2, varscan2
- PCSK5 | c.2831G>A p.G944E | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV70450490; called by muse, mutect2, varscan2
- PDCL3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs945388318, COSV51809500; called by muse, mutect2, varscan2
- PDE11A | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); catalogued as COSV53698335; called by muse, mutect2, varscan2
- PDLIM4 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 75/93 reads (81%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs1306053890, COSV53804425; called by muse, mutect2, varscan2
- PDLIM5 | c.1459C>T p.L487F | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58748998; called by muse, mutect2, varscan2
- PDYN | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1486022228, COSV54102172, COSV99452734; called by muse, mutect2
- PEG3 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV55631658; called by muse, mutect2, varscan2
- PEX5L | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV55843079; called by muse, mutect2, varscan2
- PHC1 | c.1184T>A p.I395N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV101418559; called by muse, mutect2, varscan2
- PHEX | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 90/103 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65076432; called by muse, mutect2, varscan2
- PI4KB | c.917C>T p.S306F (on ENST00000368873 / NM_001369623.1; = p.S318F on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1364707430, COSV55018687; called by muse, mutect2
- PIEZO2 | c.7501G>A p.G2501R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777837370, COSV53290844; called by muse, mutect2, varscan2
- PIH1D1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51807698; called by muse, mutect2
- PIK3CG | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.204); catalogued as COSV63249589; called by muse, mutect2, varscan2
- PIP | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1303868602, COSV52120810; called by muse, mutect2, varscan2
- PIP4K2A | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV64863595; called by muse, mutect2, varscan2
- PKD1 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs1254981533, COSV99237778; called by mutect2, varscan2
- PKHD1L1 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV65745700, COSV65746922; called by muse, mutect2, varscan2
- PKNOX2 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53548214; called by muse, mutect2, varscan2
- PKP1 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1226887996, COSV55822269; called by muse, mutect2, varscan2
- PLAAT1 | c.368G>A p.G123E (on ENST00000650797; = p.G18E on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53229964; called by muse, mutect2, varscan2
- PLAG1 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1327977649, COSV57612316; called by muse, mutect2, varscan2
- PLB1 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV59828370; called by muse, mutect2, varscan2
- PLBD1 | c.1592A>C p.Q531P | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.447); catalogued as COSV53694330; called by muse, mutect2
- PLCL2 | c.1940C>T p.S647F (on ENST00000615277 / NM_001144382.2; = p.S521F on NM_015184.5) | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67621175; called by muse, mutect2, varscan2
- PMEPA1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs1392152801, COSV99671678; called by muse, mutect2, varscan2
- PMEPA1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs924182556, COSV55696564; called by muse, mutect2, varscan2
- POF1B | c.1650-1G>A p.X550_splice | Splice Site (SNP) | VAF 23/25 reads (92%) | catalogued as COSV53135686; called by muse, mutect2, varscan2
- POLDIP3 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV52809387; called by muse, varscan2
- POTEA | c.1288G>A p.D430N (on ENST00000519951 / NM_001005365.2; = p.D384N on NM_001002920.1) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs867210076; called by muse, mutect2, varscan2
- POTEE | c.1720A>T p.K574* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100387520; called by mutect2, varscan2
- POU2F3 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1381978446, COSV52794899; called by muse, mutect2, varscan2
- POU6F1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV61327030; called by muse, mutect2, varscan2
- PPIH | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV59246212; called by muse, mutect2, varscan2
- PPIL2 | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100622545; called by muse, mutect2, varscan2
- PPP2R2C | c.650A>G p.N217S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV58673416; called by muse, mutect2, varscan2
- PRAMEF1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs374188640; called by muse, mutect2, varscan2
- PRDM10 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58802138; called by muse, mutect2, varscan2
- PRIM2 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV67295445, COSV67301238; called by muse, mutect2, varscan2
- PRKCQ | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.79); PolyPhen benign (0.112); catalogued as COSV99576653; called by muse, mutect2, varscan2
- PRKCQ | c.121A>T p.N41Y | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV54106415; called by muse, mutect2, varscan2
- PROC | c.1331G>A p.W444* | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | catalogued as CM005562, COSV52166513; called by muse, mutect2, varscan2
- PRPF40B | c.2011G>A p.E671K (on ENST00000380281; = p.E658K on NM_012272.3) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV53303553; called by muse, mutect2, varscan2
- PRPF4B | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs775187928, COSV61784512; called by muse, mutect2, varscan2
- PRRC2A | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs759776981, COSV101051098; called by muse, mutect2, varscan2
- PRRC2A | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV101051100; called by muse, mutect2, varscan2
- PRUNE2 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65042979; called by muse, mutect2, varscan2
- PSG7 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 101/211 reads (48%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.971); catalogued as rs1370553446, COSV68445186; called by muse, mutect2, varscan2
- PSG9 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as COSV52485819; called by muse, mutect2, varscan2
- PTGDR | c.853G>C p.A285P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100035572, COSV60094230; called by muse, mutect2
- PTGIS | c.926T>A p.V309D | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1031592502, COSV54837988; called by muse, mutect2, varscan2
- PTK7 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57848776; called by muse, mutect2, varscan2
- PTPRB | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as rs1396889536, COSV51726186; called by muse, mutect2, varscan2
- PTPRE | c.1545G>A p.W515* | Nonsense Mutation (SNP) | VAF 27/37 reads (73%) | catalogued as COSV54552938; called by muse, mutect2, varscan2
- PTPRN2 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs540718162, COSV67044237; called by muse, mutect2, varscan2
- PTPRU | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs761211287, COSV60530007; called by muse, mutect2, varscan2
- PTX4 | c.446C>T p.A149V (on ENST00000447419 / NM_001328608.2; = p.A144V on NM_001013658.1) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV53517499; called by muse, mutect2, varscan2
- PXDNL | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1390297647, COSV62487318; called by muse, mutect2, varscan2
- RAB11FIP1 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 60/146 reads (41%) | catalogued as COSV54761124; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51483907; called by muse, mutect2, varscan2
- RANBP3L | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.55); PolyPhen benign (0.162); catalogued as COSV56956256; called by muse, mutect2, varscan2
- RAPGEF4 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51379079; called by muse, mutect2, varscan2
- RASEF | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV64587567; called by muse, mutect2, varscan2
- RASGRF2 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 86/120 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs867389213, COSV54132009; called by muse, mutect2, varscan2
- RASGRP1 | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV60365736; called by muse, mutect2, varscan2
- RB1 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD034936, CM030504, COSV57307935, COSV57323260; called by muse, mutect2, varscan2
- RB1 | c.1685C>A p.A562E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99924142; called by muse, mutect2, varscan2
- RBM47 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1047835662, COSV55931130; called by muse, mutect2, varscan2
- RECQL4 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99467410; called by muse, mutect2, varscan2
- REL | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs767519747, COSV54362148; called by muse, mutect2, varscan2
- REST | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1560452115, COSV58361289; called by muse, mutect2, varscan2
- RFX3 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1469370725, COSV56518171; called by muse, mutect2, varscan2
- RFX4 | c.538G>A p.E180K (on ENST00000392842 / NM_213594.3; = p.E86K on NM_032491.6) | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV57576946; called by muse, mutect2, varscan2
- RGL1 | c.980C>T p.S327F (on ENST00000360851 / NM_001297672.2; = p.S362F on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868356084, COSV58987925; called by muse, mutect2, varscan2
- RGS1 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV66505615; called by muse, mutect2, varscan2
- RGS22 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV62663219; called by muse, mutect2, varscan2
- RGS6 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59563456; called by muse, mutect2, varscan2
- RGS7 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58534432, COSV58536758; called by muse, mutect2, varscan2
- RHBDD3 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53323728; called by muse, mutect2, varscan2
- RHPN2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs766609551, COSV54280624; called by muse, mutect2, varscan2
- RIMBP2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373251521; called by muse, varscan2
- RIMS4 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV65719938; called by muse, mutect2, varscan2
- RNASEL | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62377201; called by muse, mutect2, varscan2
- ROBO4 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60625191; called by muse, mutect2, varscan2
- ROGDI | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751253265, COSV58927564; called by muse, mutect2, varscan2
- ROS1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV63854206; called by muse, mutect2, varscan2
- RP1 | c.3868C>T p.Q1290* | Nonsense Mutation (SNP) | VAF 61/176 reads (35%) | catalogued as COSV55111908; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.311T>G p.L104R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV59087807; called by muse, mutect2, varscan2
- RPLP2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV58252778; called by muse, mutect2, varscan2
- RPRM | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV57988898; called by muse, mutect2, varscan2
- RRP12 | c.1583C>A p.T528K | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV59668696; called by muse, mutect2, varscan2
- RS1 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.25); PolyPhen benign (0.388); catalogued as COSV66106783; called by muse, mutect2, varscan2
- RSC1A1 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs754021065, COSV60780098; called by muse, mutect2, varscan2
- RSPH6A | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV55571032; called by muse, mutect2, varscan2
- RUNDC3B | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0.091); catalogued as COSV56691470, COSV56692569; called by muse, mutect2, varscan2
- RYR1 | c.10297G>A p.E3433K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV62090797; called by muse, mutect2, varscan2
- RYR2 | c.10924G>A p.E3642K | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV63692158; called by muse, mutect2, varscan2
- RYR3 | c.5065G>A p.E1689K | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs1204413940, COSV66795378; called by muse, mutect2, varscan2
- S1PR4 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV55740585; called by muse, mutect2, varscan2
- SAC3D1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.398); catalogued as COSV57247368; called by muse, mutect2, varscan2
- SAG | c.732C>T p.F244= | Splice Region (SNP) | VAF 20/29 reads (69%) | catalogued as rs377600235, COSV68591334; called by muse, mutect2
- SAMD7 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59416808; called by muse, mutect2, varscan2
- SAMD9L | c.3931G>A p.D1311N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV59082574; called by muse, mutect2, varscan2
- SCIN | c.1489G>A p.G497R (on ENST00000297029 / NM_001112706.3; = p.G250R on NM_033128.3) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51694260, COSV99765099; called by muse, mutect2, varscan2
- SCN10A | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1559437259, COSV71861832; called by muse, mutect2, varscan2
- SCN1A | c.5798G>A p.R1933Q (on ENST00000303395 / NM_001202435.3; = p.R1922Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs556893466, COSV57662668; called by muse, mutect2, varscan2
- SCN2A | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51845597; called by muse, mutect2, varscan2
- SEMA3A | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV54874754, COSV54875795; called by muse, mutect2, varscan2
- SEPTIN14 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV101193396, COSV66428430; called by muse, mutect2, varscan2
- SERPINA10 | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV100003737; called by muse, mutect2, varscan2
- SERPINB13 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54029194; called by muse, mutect2, varscan2
- SERPINB2 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV55093105; called by muse, mutect2, varscan2
- SERPING1 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.353); catalogued as rs760283415, COSV53542906; called by muse, mutect2, varscan2
- SERPINI2 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52986799, COSV99248029; called by muse, mutect2, varscan2
- SEZ6 | c.2471G>A p.S824N | Missense Mutation (SNP) | VAF 116/156 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.388); catalogued as rs372572005; called by muse, mutect2, varscan2
- SEZ6L | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV50666514; called by muse, mutect2, varscan2
- SGCZ | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.961); catalogued as COSV66021596; called by muse, mutect2, varscan2
- SGMS1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867467927, COSV62370723; called by muse, varscan2
- SGSM1 | c.2305C>T p.H769Y (on ENST00000400359 / NM_001039948.4; = p.H708Y on NM_133454.3) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.696); catalogued as rs1270943241, COSV63082534; called by muse, mutect2, varscan2
- SH2B3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs752520582, COSV100374172; called by muse, mutect2, varscan2
- SH2D2A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV63884967; called by muse, mutect2, varscan2
- SHISA3 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 138/276 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs140353032; called by muse, mutect2, varscan2
- SI | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs201140811, COSV52284285; called by muse, mutect2, varscan2
- SIGLEC6 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as rs750482700, COSV58435285; called by muse, mutect2, varscan2
- SIM1 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.14); catalogued as rs1175589349, COSV53493399; called by muse, mutect2, varscan2
- SLA | c.49C>T p.P17S (on ENST00000338087 / NM_001045556.3; = p.P57S on NM_006748.4) | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55081082, COSV55088904; called by muse, mutect2, varscan2
- SLAMF9 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs200703097, COSV63636839; called by muse, mutect2, varscan2
- SLC16A10 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64354500; called by muse, mutect2, varscan2
- SLC24A3 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 309/505 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60122610, COSV60122854; called by muse, mutect2, varscan2
- SLC25A45 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); catalogued as COSV53684162; called by muse, mutect2, varscan2
- SLC25A45 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53684169, COSV99587347; called by muse, mutect2, varscan2
- SLC29A2 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237061; called by muse, mutect2, varscan2
- SLC29A2 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237062; called by muse, mutect2, varscan2
- SLC2A13 | c.1022T>C p.I341T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99786305; called by muse, mutect2, varscan2
- SLC2A6 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64142852; called by muse, mutect2, varscan2
- SLC38A3 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68844058; called by muse, mutect2, varscan2
- SLC39A3 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs35127617, COSV54118321; called by muse, mutect2, varscan2
- SLC41A1 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65650796; called by muse, mutect2, varscan2
- SLC43A3 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV61450614; called by muse, mutect2, varscan2
- SLC46A3 | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 27/49 reads (55%) | catalogued as COSV57182444; called by muse, mutect2, varscan2
- SLC4A5 | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs866262420, COSV61025711; called by muse, mutect2
- SLC4A7 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.105); catalogued as rs771750085, COSV55398824; called by muse, mutect2, varscan2
- SLC5A8 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV73310794; called by muse, mutect2, varscan2
- SLC6A13 | c.840G>A p.M280I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV58257822; called by muse, mutect2, varscan2
- SLC6A6 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV62650527; called by muse, mutect2, varscan2
- SLC9A4 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as rs762876917, COSV54835414; called by muse, mutect2, varscan2
- SLCO1A2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as rs866943138, COSV56601007, COSV56602235; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1938T>G p.I646M (on ENST00000540229 / NM_001371097.1; = p.I585M on NM_001009562.4) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as COSV67445355; called by muse, mutect2, varscan2
- SNAPC2 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs537522374, COSV54491237; called by muse, mutect2, varscan2
723 further variants in this file (185 protein-altering or splice-affecting, 505 silent, 33 other) are not listed here.
